Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5726, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5726-01A (Primary Tumor).

Diagnosis:

This is a moderately differentiated gastric carcinoma of the intestinal type according to

Moderate degree of differentiation

Dissemination pattern: Infiltration of submucosa, therefore corresponding to pT1.

Otherwise free resection margins and free lymph nodes.

Tumor classification:

ICDO-DA-M 8140/3

PT1, pN0.

Source: NCI Genomic Data Commons file ba9bcf8a-b3bb-4329-b354-8a4ff0d86db8 (TCGA-CG-5726.600E3AB6-0247-43C2-8A5E-6D7378B1B49A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).